Somatic mutation profile of tumor specimen C3L-00361-01 (aliquot CPT0002430008) from CPTAC case C3L-00361, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 64.2 years (23,458 days).
Specimen C3L-00361-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1450021e-dd4b-4072-bb65-e07e97ba7d3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00361-31 (Blood Derived Normal), aliquot CPT0004400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61f6b9a7-7ddf-454c-a2b4-1a1cb895a765

The open-access MAF lists 872 somatic variants for this specimen: 601 protein-altering or splice-affecting, 146 silent, 125 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 429, Silent 146, Frame Shift Del 90, Intron 64, Nonsense Mutation 26, 3'UTR 24, Frame Shift Ins 22, 5'UTR 15, Splice Region 13, Splice Site 12, RNA 9, In Frame Del 8.

Variants (750 of 872; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 147/340 reads (43%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 158/412 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 28/64 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 33/238 reads (14%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.1738dup p.Y580Lfs*8 | Frame Shift Ins (INS) | VAF 54/164 reads (33%) | catalogued as rs786204255; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 126/339 reads (37%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCA7 | c.1929C>A p.S643R | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1408562566; called by muse, mutect2, varscan2
- ACADVL | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 220/550 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.106); catalogued as rs1470149388; called by muse, mutect2, varscan2
- ADAM11 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751824828, COSV52347729; called by muse, mutect2, varscan2
- ADAM17 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs750951308, COSV100176734; called by muse, varscan2
- ADAMTS13 | c.3029A>G p.E1010G | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as rs886493351; called by muse, mutect2, varscan2
- ADGRV1 | c.626del p.P209Lfs*6 | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | catalogued as rs756977835, COSV101316537, COSV67977494; called by mutect2, pindel, varscan2
- AKAP17A | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.714); catalogued as rs193269079; called by muse, mutect2, varscan2
- AKT1 | c.157A>C p.N53H | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100838124; called by muse, mutect2, varscan2
- AMER2 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1360018508; called by muse, mutect2, varscan2
- ANO5 | c.1484T>C p.M495T | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs771881830; called by muse, mutect2, varscan2
- AP4B1 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 123/254 reads (48%) | catalogued as rs777248758; called by muse, mutect2, varscan2
- AP5Z1 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as rs1439707706, COSV62241370; called by muse, mutect2, varscan2
- APBA1 | c.1113del p.D372Tfs*84 | Frame Shift Del (DEL) | VAF 63/157 reads (40%) | catalogued as COSV55233726; called by mutect2, pindel, varscan2
- ARFGEF2 | c.4438A>G p.T1480A | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1568740066; called by muse, mutect2, varscan2
- ARGLU1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1461351137; called by muse, mutect2, varscan2
- ARHGEF38 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs773873939, COSV101337662; called by muse, mutect2, varscan2
- ARSH | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs753484979; called by muse, mutect2, varscan2
- ASB10 | c.472G>A p.A158T (on ENST00000420175 / NM_001142459.2; = p.A143T on NM_080871.4) | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as rs144079446; called by muse, mutect2, varscan2
- ASB14 | c.371del p.L124Wfs*8 (on ENST00000389601; = p.L123Wfs*8 on NM_001142733.3) | Frame Shift Del (DEL) | VAF 44/136 reads (32%) | catalogued as rs770471078; called by mutect2, varscan2
- ATP8B4 | c.1090T>C p.Y364H | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99463999; called by muse, mutect2
- ATRN | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1039364929, COSV99496944; called by muse, varscan2
- BAIAP2 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 127/292 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100349055; called by muse, mutect2, varscan2
- BEND7 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 64/175 reads (37%) | PolyPhen benign (0); catalogued as rs754419392; called by muse, mutect2, varscan2
- BICDL1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs1218454984; called by muse, mutect2, varscan2
- BMI1 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV64959031; called by muse, mutect2, varscan2
- BPTF | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV58835792; called by muse, mutect2
- BRINP2 | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 95/389 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV64178505; called by muse, mutect2, varscan2
- BTBD1 | c.1143+4_1143+5del | Splice Region (DEL) | VAF 27/71 reads (38%) | catalogued as rs1296741540; called by mutect2, pindel, varscan2
- BTBD7 | c.2530A>G p.T844A | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58283930; called by muse, mutect2, varscan2
- BTK | c.1881_1882dup p.T628Ifs*22 | Frame Shift Ins (INS) | VAF 80/217 reads (37%) | catalogued as CI951916; called by mutect2, pindel, varscan2
- BUD13 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs12272017; called by muse, mutect2, varscan2
- C10orf71 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs374875968; called by muse, mutect2, varscan2
- C5orf38 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV57411549; called by muse, varscan2
- CACNA1F | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59905832; called by mutect2, varscan2
- CACNA1G | c.3128C>T p.T1043M | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs762839886; called by muse, mutect2, varscan2
- CAD | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373210754, COSV53029198; called by muse, mutect2, varscan2
- CADM4 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV99731465; called by muse, mutect2, varscan2
- CCDC7 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as rs1257132495, COSV100178954, COSV56551755; called by muse, mutect2, varscan2
- CCR1 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.552); catalogued as rs200413728; called by muse, mutect2, varscan2
- CDC73 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 105/472 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs748952219, COSV66470933; called by muse, mutect2, varscan2
- CDK11A | c.110del p.N37Ifs*17 | Frame Shift Del (DEL) | VAF 46/164 reads (28%) | catalogued as rs767014805; called by mutect2, pindel, varscan2
- CDK2AP1 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55542333; called by muse, mutect2, varscan2
- CENPE | c.5840T>A p.I1947N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs1034702496, COSV54381682; called by muse, mutect2, varscan2
- CENPJ | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 104/267 reads (39%) | catalogued as rs757159265, COSV101121442; called by muse, mutect2, varscan2
- CENPX | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs751693583; called by muse, mutect2, varscan2
- CFAP46 | c.5008G>A p.G1670R | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs535798930; called by muse, mutect2, varscan2
- CFAP46 | c.3044C>T p.T1015M | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs898358192; called by muse, mutect2, varscan2
- CHRNA7 | c.1281del p.E428Rfs*60 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs778298112; called by mutect2, varscan2
- CHRNA9 | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.221); catalogued as COSV100038923; called by muse, mutect2, varscan2
- COG7 | c.1897T>A p.Y633N | Missense Mutation (SNP) | VAF 112/234 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56150012; called by muse, mutect2, varscan2
- COL19A1 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100504978; called by muse, mutect2, varscan2
- COL9A1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 105/247 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs150026024, COSV61833381; called by muse, mutect2, varscan2
- COX18 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs1167807810; called by muse, mutect2, varscan2
- CPNE7 | c.817-2A>G p.X273_splice | Splice Site (SNP) | VAF 60/138 reads (43%) | catalogued as rs745965207; called by muse, mutect2, varscan2
- CRTAC1 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs755410645, COSV54004200; called by muse, mutect2, varscan2
- CRX | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 117/276 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs761797993, COSV99704477; called by muse, mutect2, varscan2
- CRYBG1 | c.2716G>T p.E906* | Nonsense Mutation (SNP) | VAF 43/172 reads (25%) | catalogued as COSV64811517; called by muse, mutect2, varscan2
- CSMD3 | c.5092C>T p.R1698* (on ENST00000297405 / NM_001363185.1; = p.R1594* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 111/288 reads (39%) | catalogued as rs778555238, COSV52257393; called by muse, mutect2, varscan2
- CSNK2A1 | c.843G>T p.W281C | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53937095; called by muse, mutect2, varscan2
- CTDP1 | c.1189C>A p.R397S | Missense Mutation (SNP) | VAF 109/221 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV50002848, COSV50009557; called by muse, mutect2, varscan2
- CTSA | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 149/371 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs979929353; called by muse, mutect2, varscan2
- CXCR1 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs753898469, COSV55281833; called by muse, mutect2, varscan2
- CYP2W1 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417260; called by muse, mutect2, varscan2
- DAB2IP | c.1157C>T p.T386M (on ENST00000408936; = p.T358M on NM_032552.3) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as rs554336776, COSV52254798; called by muse, mutect2, varscan2
- DCAF12L2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 133/260 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV63580758, COSV63582325; called by muse, mutect2, varscan2
- DCHS1 | c.5132G>A p.R1711Q | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1466443387, COSV55042027; called by muse, mutect2
- DCHS1 | c.4738G>A p.V1580M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1198033565, COSV55032301; called by muse, mutect2, varscan2
- DHX33 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV56580327; called by muse, mutect2, varscan2
- DMXL2 | c.5077_5079del p.T1693del | In Frame Del (DEL) | VAF 32/70 reads (46%) | catalogued as rs1352586892; called by pindel, varscan2
- DNAH14 | c.8110C>T p.R2704C (on ENST00000445597; = p.R3507C on NM_001367479.1) | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1213273691; called by muse, mutect2, varscan2
- DUSP7 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as rs765442575; called by muse, mutect2, varscan2
- EFS | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs369972669; called by muse, varscan2
- EMC8 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as rs1027748374, COSV53667749; called by muse, mutect2, varscan2
- EMILIN1 | c.945G>T p.Q315H | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV53152868; called by muse, mutect2, varscan2
- EPDR1 | c.416dup p.G140Rfs*19 | Frame Shift Ins (INS) | VAF 84/222 reads (38%) | catalogued as rs1233512979; called by mutect2, varscan2
- EPHA4 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.414); catalogued as rs981128868, COSV56035060; called by muse, mutect2, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs756461692; called by mutect2, varscan2
- ERN2 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs143641485; called by muse, mutect2, varscan2
- EVPL | c.5626C>T p.R1876C | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367629091, COSV56914897; called by muse, mutect2, varscan2
- F8 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372867215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM86B1 | c.442del p.R148Gfs*27 | Frame Shift Del (DEL) | VAF 134/716 reads (19%) | catalogued as COSV58669078; called by mutect2, varscan2
- FAN1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs565689759; called by muse, mutect2, varscan2
- FANCI | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772266177; called by mutect2, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 136/350 reads (39%) | catalogued as rs747011618; called by mutect2, varscan2
- FBLN1 | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 147/359 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1448100542; called by muse, mutect2, varscan2
- FLCN | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 183/413 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs748031634, COSV53256804, COSV99550761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.5374G>A p.A1792T | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201348102; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FOXM1 | c.2008dup p.L670Pfs*2 | Frame Shift Ins (INS) | VAF 57/139 reads (41%) | catalogued as rs745702333; called by mutect2, varscan2
- FRY | c.636-2A>G p.X212_splice | Splice Site (SNP) | VAF 149/375 reads (40%) | catalogued as COSV100969108; called by muse, mutect2, varscan2
- FUNDC2 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV64274074; called by muse, mutect2, varscan2
- GALNT11 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776094150; called by muse, mutect2, varscan2
- GALNTL5 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 99/255 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV67181587; called by muse, mutect2, varscan2
- GAREM2 | c.2126G>A p.G709D | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs1234836390; called by muse, mutect2, varscan2
- GCN1 | c.6851C>T p.A2284V | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100325642; called by muse, mutect2, varscan2
- GIGYF1 | c.746A>C p.K249T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs910324775; called by muse, mutect2, varscan2
- GINS3 | c.469T>A p.Y157N | Missense Mutation (SNP) | VAF 102/219 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as COSV58920620; called by muse, mutect2, varscan2
- GLB1L | c.1191_1194del p.H397Qfs*5 | Frame Shift Del (DEL) | VAF 48/120 reads (40%) | catalogued as rs1366323396; called by pindel, varscan2
- GLI3 | c.2962G>A p.G988R | Missense Mutation (SNP) | VAF 139/341 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs765236732, COSV101229894; called by muse, mutect2, varscan2
- GLT6D1 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65627972; called by muse, mutect2, varscan2
- GMEB2 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs557372683; called by muse, mutect2, varscan2
- GMFB | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1301969496, COSV63738204; called by muse, mutect2, varscan2
- GMNN | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV100017663; called by muse, mutect2, varscan2
- GNAS | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 108/261 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1295350827, COSV58330745; called by muse, mutect2, varscan2
- GRM2 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as rs567499268, COSV56583341; called by muse, mutect2, varscan2
- GZF1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100582727; called by muse, mutect2, varscan2
- HECTD4 | c.8140G>A p.A2714T | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66390225; called by muse, mutect2, varscan2
- HOXB7 | c.191del p.G64Afs*99 | Frame Shift Del (DEL) | VAF 32/71 reads (45%) | catalogued as rs761197780; called by mutect2, varscan2
- HUWE1 | c.2372A>G p.Q791R | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53332820; called by muse, mutect2, varscan2
- IGF2R | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.138); catalogued as rs1255755364; called by muse, mutect2, varscan2
- IGFN1 | c.3409C>T p.Q1137* (on ENST00000295591 / NM_001367841.1; = p.Q3594* on NM_001164586.2) | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as rs143048291; called by muse, mutect2, varscan2
- IL19 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs367592655; called by muse, mutect2, varscan2
- ILF3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs777180134; called by muse, mutect2, varscan2
- INPP5J | c.1586C>T p.T529M (on ENST00000331075 / NM_001284285.2; = p.T161M on NM_001002837.2) | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768472551, COSV58514286; called by muse, mutect2, varscan2
- INTS1 | c.4561G>A p.V1521I | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs759138761, COSV67177245; called by muse, mutect2, varscan2
- JAG2 | c.3466C>T p.P1156S | Missense Mutation (SNP) | VAF 130/279 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772503929; called by muse, mutect2, varscan2
- JCAD | c.3373dup p.Q1125Pfs*19 | Frame Shift Ins (INS) | VAF 51/165 reads (31%) | catalogued as rs886043177; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 68/192 reads (35%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCTD13 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.618); catalogued as rs758482954, COSV100441710; called by muse, mutect2, varscan2
- KIF2A | c.550dup p.R184Kfs*6 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | catalogued as rs1177534801; called by mutect2, pindel, varscan2
- KLF4 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs139364854, COSV101012649; called by muse, mutect2, varscan2
- KLHL17 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372872551; called by muse, mutect2, varscan2
- KLK15 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs1206224835, COSV100032573, COSV56826168; called by muse, mutect2, varscan2
- KLK2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV57571225; called by muse, mutect2, varscan2
- KMT2D | c.9391_9393del p.P3131del | In Frame Del (DEL) | VAF 42/170 reads (25%) | catalogued as rs748239185; called by mutect2, pindel, varscan2
- KRTAP10-1 | c.282del p.C95Afs*233 | Frame Shift Del (DEL) | VAF 217/582 reads (37%) | catalogued as COSV59961454; called by mutect2, pindel, varscan2
- LAMA4 | c.4059T>A p.F1353L (on ENST00000230538 / NM_001105206.3; = p.F1346L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs782273793, COSV57904686; called by muse, mutect2
- LAMA4 | c.1613C>T p.A538V (on ENST00000230538 / NM_001105206.3; = p.A531V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/370 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs782569832, COSV57892683; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMB3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 83/441 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs762942741, COSV61920286; called by muse, mutect2, varscan2
- LAMB4 | c.4870C>T p.R1624* | Nonsense Mutation (SNP) | VAF 85/216 reads (39%) | catalogued as rs755641480, COSV52732528; called by muse, varscan2
- LAMC3 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as rs1394227732, COSV63093963; called by muse, mutect2
- LCK | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 124/297 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs371877562; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 72/181 reads (40%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LRIG3 | c.2491T>C p.Y831H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372026653; called by muse, mutect2
- LRIT1 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 122/314 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV64513156; called by muse, mutect2, varscan2
- LRRC4C | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.981); catalogued as rs1450656731, COSV53419909, COSV99538496; called by muse, mutect2, varscan2
- LRRC71 | c.159T>C p.P53= | Splice Region (SNP) | VAF 26/106 reads (25%) | catalogued as rs573203048; called by muse, mutect2, varscan2
- LRRN4 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 103/265 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1230388275; called by muse, mutect2, varscan2
- LTBP2 | c.5172G>A p.E1724= | Splice Region (SNP) | VAF 92/202 reads (46%) | catalogued as rs1051538171; called by muse, mutect2, varscan2
- LYVE1 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as rs775409214, COSV56283682; called by muse, mutect2
- MAD1L1 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs752885094, COSV56231834; called by muse, mutect2, varscan2
- MADD | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs773065625; called by muse, mutect2, varscan2
- MAGEB18 | c.923G>T p.R308M | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV57464706; called by muse, mutect2, varscan2
- MAGED1 | c.1516A>G p.T506A | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.014); catalogued as rs782365292; called by muse, mutect2, varscan2
- MAN2C1 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as rs1164276408; called by muse, mutect2, varscan2
- MAP3K21 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 131/195 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs1044791348; called by muse, mutect2, varscan2
- MARCHF11 | c.653G>T p.R218I | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV60133758; called by muse, mutect2, varscan2
- MCF2L2 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293584286, COSV61049822; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MEIS1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55483591; called by muse, mutect2, varscan2
- MFSD14B | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1400273184; called by muse, mutect2, varscan2
- MGA | c.6276del p.A2093Pfs*9 (on ENST00000219905 / NM_001164273.1; = p.A1884Pfs*9 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 44/122 reads (36%) | catalogued as COSV99580432; called by mutect2, varscan2
- MORC3 | c.2213A>G p.Y738C | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1448613337; called by muse, mutect2, varscan2
- MPV17 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 141/323 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs374686068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPL40 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV54273821; called by muse, mutect2, varscan2
- MTARC2 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs746721056; called by muse, mutect2, varscan2
- MUC16 | c.14758C>A p.L4920I | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.246); catalogued as COSV67484417; called by muse, mutect2, varscan2
- MUC5AC | c.13990del p.I4664Sfs*21 | Frame Shift Del (DEL) | VAF 75/197 reads (38%) | catalogued as rs771848118; called by mutect2, pindel, varscan2
- MUC5B | c.15146G>A p.C5049Y | Missense Mutation (SNP) | VAF 113/312 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71589945; called by muse, varscan2
- MUC6 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1209093999; called by muse, mutect2, varscan2
- MYCT1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1364305353; called by muse, mutect2, varscan2
- MYH10 | c.3776C>T p.A1259V | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs765363104, COSV52605448; called by muse, mutect2, varscan2
- MYH10 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs1455227893; called by muse, mutect2
- MYH14 | c.1830G>A p.W610* | Nonsense Mutation (SNP) | VAF 36/137 reads (26%) | catalogued as COSV99222552; called by muse, mutect2, varscan2
- MYO5B | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 208/477 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746895518; called by muse, mutect2, varscan2
- MYOM3 | c.4022C>T p.P1341L | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961510485, COSV58393283; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 46/100 reads (46%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- NAALADL1 | c.2060del p.T687Rfs*4 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as COSV57246981; called by mutect2, pindel, varscan2
- NAV2 | c.6178C>T p.R2060W (on ENST00000396087 / NM_001244963.2; = p.R2001W on NM_145117.5) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146972682; called by muse, mutect2, varscan2
- NPFFR1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.248); catalogued as rs1371977520; called by muse, mutect2, varscan2
- NPR1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1290716134; called by muse, mutect2, varscan2
- NRG3 | c.1795C>A p.P599T (on ENST00000404547 / NM_001370084.1; = p.P575T on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/256 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64582341; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 48/96 reads (50%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP210 | c.1395G>A p.W465* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as rs1418672448; called by muse, mutect2, varscan2
- OGFR | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs757955533, COSV51701872; called by muse, mutect2, varscan2
- OPRPN | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV68192554; called by muse, mutect2, varscan2
- OR14K1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 69/290 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs775731872; called by muse, mutect2, varscan2
- OR4X2 | c.213del p.K72Nfs*38 | Frame Shift Del (DEL) | VAF 74/177 reads (42%) | catalogued as rs757093215; called by mutect2, pindel, varscan2
- OR52B4 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as rs767367023, COSV68769096; called by muse, mutect2, varscan2
- OR5M11 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs544158488, COSV73141926; called by muse, mutect2, varscan2
- PAIP1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as rs1400821137; called by muse, mutect2, varscan2
- PAPPA2 | c.3845del p.L1282* | Frame Shift Del (DEL) | VAF 48/232 reads (21%) | catalogued as rs1558553713; called by mutect2, pindel, varscan2
- PCDHA7 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV65345073; called by muse, mutect2, varscan2
- PCDHB8 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 151/339 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs782378226, COSV50793440; called by muse, mutect2, varscan2
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 115/294 reads (39%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2, varscan2
- PCLO | c.4202G>A p.S1401N | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs929888300; called by muse, mutect2, varscan2
- PELI3 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.662); catalogued as rs1225139301; called by muse, mutect2, varscan2
- PEX11B | c.288C>G p.Y96* | Nonsense Mutation (SNP) | VAF 68/344 reads (20%) | catalogued as COSV57163121; called by muse, mutect2, varscan2
- PFKFB4 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 78/243 reads (32%) | PolyPhen probably damaging (0.999); catalogued as rs776332395; called by muse, mutect2, varscan2
- PIGR | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.118); catalogued as rs370527545; called by muse, mutect2, varscan2
- PITPNM2 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs779013183, COSV54908128; called by muse, mutect2, varscan2
- PIWIL1 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.664); catalogued as rs1053363818, COSV55346039; called by muse, mutect2, varscan2
- PKHD1 | c.7477C>A p.Q2493K | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs540449958, CM034275, COSV61876856; called by muse, mutect2, varscan2
- PLCG2 | c.2152A>G p.S718G | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs767628464, COSV63870875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA4 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV54367638; called by muse, mutect2, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 32/82 reads (39%) | catalogued as rs746342377; called by mutect2, varscan2
- PLPPR3 | c.787G>A p.V263M (on ENST00000520876 / NM_001270366.2; = p.V291M on NM_024888.2) | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1332303575, COSV62460996; called by muse, mutect2, varscan2
- PLXNA2 | c.5666C>T p.A1889V | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.057); catalogued as rs1252577059, COSV100885194; called by muse, mutect2, varscan2
- POLD1 | c.347del p.P116Hfs*53 | Frame Shift Del (DEL) | VAF 71/191 reads (37%) | catalogued as COSV101486926; called by mutect2, pindel, varscan2
- POLQ | c.5857C>T p.R1953* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as rs150312701; called by muse, mutect2, varscan2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 31/207 reads (15%) | catalogued as rs775721804; called by mutect2, pindel, varscan2
- POU4F2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as rs771220976, COSV99850302; called by muse, mutect2, varscan2
- PPIL4 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142766959; called by muse, mutect2, varscan2
- PPP1R3A | c.1429dup p.I477Nfs*2 | Frame Shift Ins (INS) | VAF 42/120 reads (35%) | catalogued as rs777079549; called by mutect2, varscan2
- PRAMEF2 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 125/450 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as rs552077363; called by muse, mutect2, varscan2
- PRDM4 | c.2077G>A p.V693M | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.07); catalogued as rs137955907; called by muse, mutect2, varscan2
- PRR12 | c.37del p.H13Tfs*66 (on ENST00000615927; = p.P408Hfs*62 on NM_020719.3) | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs763575972; called by mutect2, varscan2
- PRRC2C | c.4553del p.N1518Mfs*4 (on ENST00000367742; = p.N1516Mfs*4 on NM_015172.4) | Frame Shift Del (DEL) | VAF 32/174 reads (18%) | catalogued as rs759081735; called by mutect2, varscan2
- PTPRN | c.2780A>T p.N927I | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99834183; called by muse, mutect2
- PYGB | c.2514dup p.N839Qfs*22 | Frame Shift Ins (INS) | VAF 65/183 reads (36%) | catalogued as rs759183743; called by mutect2, pindel, varscan2
- RAB11FIP4 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767462981, COSV57934494; called by muse, mutect2, varscan2
- RBBP6 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs149857282; called by muse, mutect2, varscan2
- RHOJ | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1299232020, COSV57456400; called by muse, mutect2, varscan2
- RYR3 | c.8936G>A p.R2979Q (on ENST00000389232; = p.R2980Q on NM_001036.6) | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs200346049, COSV66785492; called by muse, mutect2, varscan2
- SALL4 | c.532A>G p.N178D | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs779382096; called by muse, mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | catalogued as rs763290832; called by mutect2, varscan2
- SCARF2 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1360034898, COSV99839121; called by muse, mutect2, varscan2
- SCN4B | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1322792651; called by muse, mutect2, varscan2
- SEMA3E | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240271605, COSV100317891; called by muse, mutect2, varscan2
- SF3B2 | c.2328C>T p.D776= | Splice Region (SNP) | VAF 21/43 reads (49%) | catalogued as rs139622723; called by muse, mutect2, varscan2
- SFXN4 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747282264, COSV57459960; called by muse, mutect2, varscan2
- SHC1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 90/136 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1329571740, COSV58316384; called by muse, mutect2, varscan2
- SHISA7 | c.1380del p.P462Qfs*75 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs1275449767; called by mutect2, varscan2
- SIK2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs761239414; called by muse, mutect2, varscan2
- SIRPB2 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as rs762440362; called by muse, mutect2, varscan2
- SKIV2L | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs753399636; called by muse, mutect2, varscan2
- SLC22A2 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs576766802; called by muse, mutect2, varscan2
- SLC23A2 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as rs761611509, COSV57772790, COSV57774719; called by muse, mutect2
- SLC37A4 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV58155346; called by muse, varscan2
- SLC6A6 | c.1176del p.F392Lfs*31 | Frame Shift Del (DEL) | VAF 50/142 reads (35%) | catalogued as rs1390226414; called by mutect2, varscan2
- SLC6A9 | c.395G>A p.R132H (on ENST00000360584 / NM_201649.4; = p.R78H on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200036856, COSV62210249, COSV62210727; called by muse, mutect2, varscan2
- SLC7A11 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs749284240; called by muse, mutect2, varscan2
- SMARCA2 | c.3490G>A p.G1164R | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61805349, COSV61813393; called by muse, varscan2
- SNRK | c.1745del p.G582Afs*69 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as COSV56068428; called by mutect2, pindel, varscan2
- SP6 | c.461del p.G154Afs*30 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | catalogued as rs772840452; called by mutect2, pindel, varscan2
- SPTA1 | c.4115C>T p.A1372V | Missense Mutation (SNP) | VAF 119/592 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV63750640; called by muse, mutect2, varscan2
- SPTBN2 | c.4747C>T p.R1583* | Nonsense Mutation (SNP) | VAF 152/353 reads (43%) | catalogued as rs766400529; called by muse, mutect2, varscan2
- SYNE3 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs200153210; called by muse, mutect2
- SYNPO2L | c.2666G>A p.R889Q (on ENST00000394810 / NM_001114133.3; = p.R665Q on NM_024875.5) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1274978385, COSV65737584, COSV65738132; called by muse, mutect2, varscan2
- TAP2 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 168/385 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.426); catalogued as rs144176825; called by muse, mutect2, varscan2
- TBCD | c.2366G>A p.G789D | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs753415681; called by muse, mutect2, varscan2
- TEP1 | c.6248G>A p.R2083Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as rs768765678; called by muse, mutect2, varscan2
- TFAP2C | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 137/306 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259135577, COSV52373544; called by muse, mutect2, varscan2
- TGM2 | c.1793A>G p.K598R | Missense Mutation (SNP) | VAF 123/253 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.339); catalogued as rs1353971993; called by muse, mutect2, varscan2
- TLK1 | c.1285A>T p.N429Y | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV62633590; called by muse, mutect2, varscan2
- TLR9 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs199759037, COSV59725584; called by muse, mutect2, varscan2
- TLX2 | c.292dup p.A98Gfs*269 | Frame Shift Ins (INS) | VAF 69/182 reads (38%) | catalogued as rs1238341034; called by mutect2, varscan2
- TMEM132C | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs896773589; called by muse, mutect2, varscan2
- TMEM170A | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV100713156; called by muse, mutect2, varscan2
- TMF1 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101275455; called by muse, mutect2, varscan2
- TNFRSF10B | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 74/186 reads (40%) | catalogued as rs760766067, COSV99311154; called by muse, mutect2, varscan2
- TNFRSF1A | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as rs1224128146; called by muse, mutect2
- TNRC6B | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as COSV57295112; called by muse, mutect2, varscan2
- TRAPPC8 | c.1173del p.K391Nfs*16 | Frame Shift Del (DEL) | VAF 25/101 reads (25%) | catalogued as rs1390346780; called by mutect2, pindel, varscan2
- TRDN | c.423del p.E142Kfs*33 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs757805966; called by mutect2, pindel, varscan2
- TRIO | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771628411, COSV60083877; called by muse, mutect2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | catalogued as rs752676391; called by mutect2, varscan2
- TRIP10 | c.674C>A p.T225N | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as rs973813934; called by muse, mutect2, varscan2
- TRUB2 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs755835163; called by muse, mutect2, varscan2
- TSGA13 | c.452del p.K151Sfs*2 | Frame Shift Del (DEL) | VAF 40/122 reads (33%) | catalogued as rs782528606, COSV58404193; called by mutect2, varscan2
- TTC13 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs761168798, COSV64167879; called by muse, mutect2, varscan2
- TTC34 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as rs1247495547, COSV101285606; called by muse, mutect2, varscan2
- TTN | c.88769G>A p.S29590N (on ENST00000591111; = p.S22166N on NM_003319.4) | Missense Mutation (SNP) | VAF 69/147 reads (47%) | PolyPhen benign (0.003); catalogued as rs1060500565; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTYH2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs202079153; called by muse, mutect2, varscan2
- TUBB8 | c.227_228del p.V76Afs*49 | Frame Shift Del (DEL) | VAF 126/433 reads (29%) | catalogued as rs782058510; called by pindel, varscan2
- TUBG2 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.054); catalogued as COSV52218168; called by muse, mutect2, varscan2
- TULP2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV55477047; called by muse, mutect2, varscan2
- UMODL1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1316589168; called by muse, mutect2, varscan2
- USH2A | c.12202G>T p.G4068* | Nonsense Mutation (SNP) | VAF 76/403 reads (19%) | catalogued as COSV56353161; called by muse, mutect2, varscan2
- VDAC3 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99195128; called by muse, mutect2, varscan2
- VSTM2B | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1386909785; called by muse, mutect2, varscan2
- VWA1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.042); catalogued as rs765625698; called by muse, mutect2, varscan2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 66/92 reads (72%) | catalogued as rs756173793; called by mutect2, varscan2
- WDCP | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs751894789; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 121/286 reads (42%) | catalogued as rs746919573; called by mutect2, varscan2
- WIF1 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.741); catalogued as rs753641125, COSV99078424; called by muse, mutect2, varscan2
- WIPF2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as rs749650322; called by muse, mutect2, varscan2
- WWP1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs764215672; called by muse, mutect2, varscan2
- XKR6 | c.274del p.D92Tfs*73 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs1403895317; called by pindel, varscan2
- XRCC5 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs61752200; called by muse, mutect2, varscan2
- ZBTB16 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 186/430 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs751421431, COSV60093321; called by muse, mutect2, varscan2
- ZCCHC7 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs374266133; called by muse, mutect2, varscan2
- ZDHHC2 | c.1019A>G p.Q340R | Missense Mutation (SNP) | VAF 108/258 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs777018863; called by muse, mutect2, varscan2
- ZFHX3 | c.10215del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 39/103 reads (38%) | catalogued as rs762108866; called by mutect2, pindel, varscan2
- ZFHX4 | c.1230del p.L411Cfs*4 | Frame Shift Del (DEL) | VAF 48/150 reads (32%) | catalogued as COSV99265992; called by mutect2, pindel, varscan2
- ZGRF1 | c.2419G>T p.G807C | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100005676; called by muse, mutect2, varscan2
- ZNF197 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.543); catalogued as rs201970271, COSV100482270; called by muse, mutect2, varscan2
- ZNF276 | c.1556C>T p.S519L (on ENST00000443381 / NM_001113525.2; = p.S444L on NM_152287.4) | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57069980; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 52/126 reads (41%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF337 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs138762711; called by muse, mutect2, varscan2
- ZNF687 | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452421185; called by muse, mutect2, varscan2
- ZNF711 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV52158667; called by muse, mutect2, varscan2
- ZNF746 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.189); catalogued as rs1273433799; called by muse, mutect2, varscan2
- ZNF831 | c.3073del p.D1025Tfs*40 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs775554241, COSV64039592; called by mutect2, varscan2
- ABHD6 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- ACIN1 | c.2298T>C p.V766= | Splice Region (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- ACOD1 | c.950A>G p.Q317R | Missense Mutation (SNP) | VAF 126/295 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRB1 | c.2323A>G p.K775E | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADGRD1 | c.1300T>C p.Y434H | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AGER | c.577A>G p.M193V | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AKT1 | c.242_243insAAGGAC p.T81_T82insRT | In Frame Ins (INS) | VAF 41/67 reads (61%) | called by pindel, varscan2
- AKTIP | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALDH1L1 | c.1983-4G>T | Splice Region (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- AMOTL1 | c.2479G>T p.G827W | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ANK2 | c.5639C>A p.P1880H | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ANKK1 | c.287T>G p.I96S | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- AP3B1 | c.2071G>T p.D691Y | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- AP3D1 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APLN | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARHGAP21 | c.1283T>C p.V428A | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ARHGAP35 | c.2834del p.K945Rfs*3 | Frame Shift Del (DEL) | VAF 76/180 reads (42%) | called by mutect2, varscan2
- ASB11 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATAD3A | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ATG4D | c.1323C>A p.D441E | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP13A2 | c.1749G>T p.W583C | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B4GALT5 | c.884del p.G295Vfs*20 | Frame Shift Del (DEL) | VAF 69/173 reads (40%) | called by mutect2, pindel, varscan2
- BAMBI | c.23T>A p.I8N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- BIRC6 | c.7090G>A p.A2364T | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- BLMH | c.266del p.K89Sfs*2 | Frame Shift Del (DEL) | VAF 40/105 reads (38%) | called by mutect2, pindel, varscan2
- BRD7 | c.1401A>T p.L467F | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.194); called by muse, mutect2
- BRD8 | c.2165C>T p.A722V (on ENST00000254900 / NM_139199.2; = p.A795V on NM_006696.4) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- BSCL2 | c.782del p.G261Afs*75 | Frame Shift Del (DEL) | VAF 108/281 reads (38%) | called by mutect2, pindel, varscan2
- C1orf141 | c.848del p.P283Lfs*11 | Frame Shift Del (DEL) | VAF 58/136 reads (43%) | called by mutect2, pindel, varscan2
- C21orf91 | c.615T>G p.S205R | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, varscan2
- C4orf54 | c.4705C>A p.L1569I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- C6orf132 | c.2217G>T p.E739D | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- CALHM5 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, varscan2
- CARS2 | c.1091A>T p.Q364L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CATSPER2 | c.1556-2A>G p.X519_splice (on ENST00000321596 / NM_001282309.3; = p.X521_splice on NM_172095.4) | Splice Site (SNP) | VAF 87/253 reads (34%) | called by muse, mutect2, varscan2
- CCDC142 | c.1022-5A>G | Splice Region (SNP) | VAF 86/213 reads (40%) | called by muse, mutect2, varscan2
- CCER1 | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- CCER1 | c.296T>G p.F99C | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CCNH | c.464A>T p.N155I | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CD300C | c.62-2A>G p.X21_splice | Splice Site (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- CD33 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- CDH7 | c.1358T>G p.L453R | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CDRT15 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CENPJ | c.2750T>C p.I917T | Missense Mutation (SNP) | VAF 116/287 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRD | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 7/174 reads (4%) | called by muse, mutect2
- CKAP5 | c.876del p.K292Nfs*12 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, varscan2
- CMYA5 | c.7718A>T p.D2573V | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL6A6 | c.2591A>G p.D864G | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, varscan2
- COQ6 | c.300T>G p.S100R | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CPNE5 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRYBB1 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CSMD2 | c.9040C>T p.P3014S | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CSMD3 | c.2759A>T p.N920I (on ENST00000297405 / NM_001363185.1; = p.N816I on NM_052900.3) | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CSPG4 | c.3949A>T p.R1317W | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CTAGE6 | c.681del p.Q228Sfs*11 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | called by mutect2, varscan2
- CUL3 | c.294T>A p.N98K | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CYP11B1 | c.1437G>T p.E479D | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP26A1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DAGLA | c.1209del p.K404Rfs*4 | Frame Shift Del (DEL) | VAF 44/115 reads (38%) | called by mutect2, pindel, varscan2
- DBNDD2 | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, varscan2
- DGKA | c.823G>T p.G275* | Nonsense Mutation (SNP) | VAF 94/244 reads (39%) | called by muse, mutect2, varscan2
- DISP3 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 81/194 reads (42%) | called by muse, mutect2, varscan2
- DIXDC1 | c.967_996del p.L323_P332del (on ENST00000440460 / NM_001037954.4; = p.L112_P121del on NM_033425.4) | In Frame Del (DEL) | VAF 60/192 reads (31%) | called by mutect2, pindel
- DPY19L1 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- DRGX | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF1E1 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFCAB6 | c.4255C>T p.P1419S | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EIF3B | c.460A>G p.S154G | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- EIF3D | c.465+3A>G | Splice Region (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- ENAM | c.588+1del | Frame Shift Del (DEL) | VAF 72/216 reads (33%) | called by mutect2, pindel, varscan2
- ENO2 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.933); called by muse, mutect2
- ERICH6 | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ESRP1 | c.380T>A p.V127E | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, varscan2
- ESRP1 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, varscan2
- FAAP100 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM184A | c.1066A>G p.S356G | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FAM3C | c.349T>G p.L117V | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBN1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 124/368 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FHOD3 | c.3710T>C p.V1237A (on ENST00000359247 / NM_001281739.3; = p.V1254A on NM_025135.5) | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FIGNL1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FITM2 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 97/252 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- FOXC1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRYL | c.2904+1G>T p.X968_splice | Splice Site (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- GABPA | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA4 | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDE1 | c.434T>A p.L145H | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GDPD3 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GDPD4 | c.251T>C p.F84S | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, varscan2
- GPBP1 | c.1244T>G p.F415C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR179 | c.3735C>A p.C1245* (on ENST00000621958; = p.C1244* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 61/175 reads (35%) | called by muse, mutect2, varscan2
- GPR179 | c.1836C>A p.F612L (on ENST00000621958; = p.F611L on NM_001004334.4) | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- GPSM2 | c.254A>G p.H85R | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRID1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GSPT2 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HAT1 | c.612-1G>T p.X204_splice | Splice Site (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- HAUS7 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 121/301 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HDAC1 | c.1346_1347del p.K449Rfs*129 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel
- HERC1 | c.9188C>T p.P3063L | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HID1 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- HLF | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- HMCN1 | c.1537T>G p.F513V | Missense Mutation (SNP) | VAF 121/635 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- HMCN1 | c.4043A>G p.E1348G | Missense Mutation (SNP) | VAF 94/411 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSDL2 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IBA57 | c.534G>T p.R178S | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFI16 | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IGHG3 | c.391-1G>T p.X131_splice | Splice Site (SNP) | VAF 94/266 reads (35%) | called by muse, varscan2
- IGLV2-33 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 130/324 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGSF9 | c.3111del p.S1038Pfs*35 (on ENST00000368094 / NM_001135050.2; = p.S1022Pfs*35 on NM_020789.4) | Frame Shift Del (DEL) | VAF 60/365 reads (16%) | called by mutect2, pindel, varscan2
- IL17C | c.268dup p.V90Gfs*28 | Frame Shift Ins (INS) | VAF 44/128 reads (34%) | called by mutect2, pindel, varscan2
- INA | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- INTS2 | c.3113G>A p.C1038Y | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IRAK1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IRGQ | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2
- ISCU | c.196dup p.A66Gfs*6 (on ENST00000311893 / NM_213595.4; = p.A41Gfs*6 on NM_014301.4) | Frame Shift Ins (INS) | VAF 29/329 reads (9%) | called by mutect2, pindel
- ITGB8 | c.1701_1702del p.C567* | Frame Shift Del (DEL) | VAF 58/241 reads (24%) | called by pindel, varscan2
- IWS1 | c.2404del p.S802Afs*7 | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | called by mutect2, pindel, varscan2
- JMY | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
- KDM6B | c.3841G>A p.A1281T | Missense Mutation (SNP) | VAF 177/427 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KEL | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 113/291 reads (39%) | called by muse, mutect2, varscan2
- KL | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL12 | c.1566_1567del p.Y523Cfs*6 | Frame Shift Del (DEL) | VAF 33/126 reads (26%) | called by pindel, varscan2
- KLHL17 | c.1919C>T p.T640I | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KMT2B | c.5281T>C p.S1761P | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KNG1 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 139/323 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- KRTCAP3 | c.146A>T p.N49I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KRTCAP3 | c.214-2A>T p.X72_splice | Splice Site (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
- LAS1L | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- LDHAL6B | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LDLRAD2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- LHFPL3 | c.40A>G p.N14D | Missense Mutation (SNP) | VAF 151/331 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LMTK3 | c.2434dup p.A812Gfs*728 | Frame Shift Ins (INS) | VAF 36/88 reads (41%) | called by mutect2, varscan2
- LPA | c.3031T>C p.Y1011H | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, varscan2
- LRIG2 | c.1257T>A p.N419K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LRRC1 | c.1105A>C p.R369= | Splice Region (SNP) | VAF 45/116 reads (39%) | called by muse, mutect2
- LRRK1 | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- LRRN2 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 126/626 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY6H | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAN1B1 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 181/393 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- MAP3K20 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP7 | c.752-2A>G p.X251_splice | Splice Site (SNP) | VAF 51/137 reads (37%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.755del p.P252Lfs*24 | Frame Shift Del (DEL) | VAF 88/203 reads (43%) | called by mutect2, pindel, varscan2
- MAPKAP1 | c.289A>G p.R97G | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MBNL1 | c.218dup p.H74Tfs*13 | Frame Shift Ins (INS) | VAF 76/226 reads (34%) | called by pindel, varscan2
- MCPH1 | c.1402del p.T468Pfs*32 | Frame Shift Del (DEL) | VAF 26/265 reads (10%) | called by mutect2, pindel
- MDC1 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MDGA2 | c.2892del p.F964Lfs*9 (on ENST00000399232 / NM_001113498.2; = p.F666Lfs*9 on NM_182830.4) | Frame Shift Del (DEL) | VAF 58/170 reads (34%) | called by mutect2, pindel, varscan2
- MEX3A | c.200del p.G67Afs*60 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | called by mutect2, varscan2
- MFN2 | c.708+5C>T | Splice Region (SNP) | VAF 94/222 reads (42%) | called by muse, mutect2, varscan2
- MYCBP2 | c.4082A>T p.Q1361L (on ENST00000357337; = p.Q1399L on NM_015057.5) | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- MYCBPAP | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- MYD88 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 191/490 reads (39%) | called by muse, mutect2, varscan2
- NCAPD2 | c.1432_1434del p.E478del | In Frame Del (DEL) | VAF 43/112 reads (38%) | called by pindel, varscan2
- NES | c.3745del p.V1249Cfs*11 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 79/385 reads (21%) | called by mutect2, pindel, varscan2
- NFATC3 | c.3143_3144del p.S1048Cfs*17 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel, varscan2
- NLRP2 | c.2202-1G>T p.X734_splice | Splice Site (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- NMNAT2 | c.884A>T p.Y295F | Missense Mutation (SNP) | VAF 66/349 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NR4A2 | c.881del p.N294Mfs*7 | Frame Shift Del (DEL) | VAF 179/554 reads (32%) | called by mutect2, pindel, varscan2
- NSMCE1 | c.322T>A p.L108M | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NT5C1B | c.1del p.M1? | Frame Shift Del (DEL) | VAF 89/260 reads (34%) | called by mutect2, pindel, varscan2
- OAS3 | c.1604C>T p.T535I | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OAT | c.97del p.T33Qfs*28 | Frame Shift Del (DEL) | VAF 116/292 reads (40%) | called by mutect2, varscan2
- OBSCN | c.5738G>A p.G1913D | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OBSL1 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10D3 | c.290del p.C97Lfs*21 | Frame Shift Del (DEL) | VAF 22/224 reads (10%) | called by mutect2, varscan2
- OR52B6 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR8J1 | c.807T>A p.D269E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.12); called by muse, mutect2
- OTOP3 | c.1531_1533del p.E511del | In Frame Del (DEL) | VAF 38/87 reads (44%) | called by mutect2, pindel, varscan2
- PAK1IP1 | c.89G>A p.W30* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | called by muse, varscan2
- PAX2 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 185/452 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDH1 | c.1221T>G p.D407E | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PCDHB6 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDCL2 | c.723dup p.*242Ifs*7 | Frame Shift Ins (INS) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- PDZD4 | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PFAS | c.398del p.P133Rfs*17 | Frame Shift Del (DEL) | VAF 6/9 reads (67%) | called by mutect2, varscan2
- PHKG2 | c.913del p.R305Afs*19 | Frame Shift Del (DEL) | VAF 186/502 reads (37%) | called by mutect2, pindel, varscan2
- PHOX2B | c.803del p.G268Afs*41 | Frame Shift Del (DEL) | VAF 64/165 reads (39%) | called by mutect2, pindel, varscan2
- PIBF1 | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- PIK3R1 | c.1967G>A p.C656Y (on ENST00000521381 / NM_181523.3; = p.C386Y on NM_181504.4) | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PITPNC1 | c.563C>G p.T188S | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PITRM1 | c.919-5del | Splice Region (DEL) | VAF 41/97 reads (42%) | called by mutect2, pindel, varscan2
- PKD2L1 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.009); called by muse, mutect2
- PKHD1L1 | c.4812dup p.C1605Lfs*7 | Frame Shift Ins (INS) | VAF 35/80 reads (44%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.1949T>C p.I650T | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHG1 | c.3994A>G p.K1332E | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLK3 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLPPR1 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 113/291 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PODXL2 | c.1205G>A p.C402Y | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R11 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- PRICKLE2 | c.2349G>A p.M783I (on ENST00000295902; = p.M727I on NM_198859.4) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PRPF38B | c.1510A>G p.K504E | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRR23C | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSG5 | c.241T>C p.S81P | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- PTCH2 | c.2423A>T p.H808L | Missense Mutation (SNP) | VAF 168/445 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, varscan2
- PTCHD1 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PTPRB | c.2410del p.S804Vfs*22 | Frame Shift Del (DEL) | VAF 66/145 reads (46%) | called by mutect2, pindel, varscan2
- PWWP2B | c.65T>A p.V22E | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- RAD54B | c.1896C>A p.N632K | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RALGAPB | c.2912del p.F971Sfs*53 | Frame Shift Del (DEL) | VAF 52/160 reads (33%) | called by mutect2, pindel, varscan2
- RANBP1 | c.382T>G p.F128V | Missense Mutation (SNP) | VAF 120/367 reads (33%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RAPGEF2 | c.1564del p.S522Vfs*12 | Frame Shift Del (DEL) | VAF 69/217 reads (32%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.1817T>C p.L606P | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RASL10B | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RBM27 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RBP3 | c.1930G>T p.G644W | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RCAN2 | c.73A>G p.N25D | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGSL1 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RLF | c.4697T>C p.I1566T | Missense Mutation (SNP) | VAF 91/221 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- RLN1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF113B | c.755T>A p.I252K | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- RNF149 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 113/281 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- RNPEPL1 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RPAP1 | c.2428A>G p.S810G | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2
- RTF2 | c.433del p.S145Lfs*5 | Frame Shift Del (DEL) | VAF 34/145 reads (23%) | called by mutect2, pindel, varscan2
- SBNO1 | c.2372del p.K791Rfs*5 (on ENST00000420886; = p.K790Rfs*5 on NM_018183.5) | Frame Shift Del (DEL) | VAF 33/81 reads (41%) | called by mutect2, varscan2
- SEC31B | c.3024+4A>G | Splice Region (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- SEMA3F | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SEMA3G | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 133/294 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SETD6 | c.1172del p.G391Efs*10 (on ENST00000219315 / NM_001160305.4; = p.G367Efs*10 on NM_024860.3) | Frame Shift Del (DEL) | VAF 85/193 reads (44%) | called by mutect2, pindel, varscan2
- SEZ6 | c.1886A>G p.K629R | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SEZ6L | c.1867del p.L623Cfs*46 | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | called by mutect2, pindel, varscan2
- SHANK3 | c.2918G>A p.S973N | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SHISA7 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SIPA1L1 | c.2573C>G p.A858G | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SKOR1 | c.555C>G p.H185Q | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A13 | c.1816T>C p.W606R | Missense Mutation (SNP) | VAF 154/387 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC33A1 | c.422A>T p.K141I | Missense Mutation (SNP) | VAF 144/383 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC4A2 | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- SMG1 | c.6776C>A p.P2259H | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMPDL3A | c.1006A>G p.R336G | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SOAT1 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOS1 | c.3090dup p.Y1031Ifs*2 | Frame Shift Ins (INS) | VAF 50/162 reads (31%) | called by mutect2, varscan2
- SPAG8 | c.502G>T p.V168F | Missense Mutation (SNP) | VAF 155/349 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- SPARCL1 | c.891G>T p.E297D | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SPATC1 | c.1030del p.Q344Rfs*72 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- SPINK5 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SREK1 | c.1047dup p.E350Rfs*4 | Frame Shift Ins (INS) | VAF 89/255 reads (35%) | called by mutect2, pindel, varscan2
- SRSF3 | c.318G>C p.R106S | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SYT14 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 242/1052 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TBX19 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 96/451 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRD12 | c.2480T>G p.V827G | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TEAD1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 20/367 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); called by muse, mutect2
- TECPR1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- TECTA | c.5575A>G p.N1859D | Missense Mutation (SNP) | VAF 127/302 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- TENT2 | c.596del p.L199Wfs*6 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by pindel, varscan2
- TEX13C | c.2907del p.P970Hfs*71 | Frame Shift Del (DEL) | VAF 87/231 reads (38%) | called by mutect2, pindel, varscan2
- THAP10 | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- THAP4 | c.1328C>A p.P443H | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLE1 | c.1860C>A p.S620R | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLE1 | c.1829+2T>C p.X610_splice | Splice Site (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2
- TMC6 | c.-75+1G>C | Splice Site (SNP) | VAF 9/253 reads (4%) | called by muse, mutect2
- TMCC2 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM178B | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMEM240 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TNR | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TP53BP2 | c.594del p.V199* (on ENST00000343537 / NM_001031685.3; = p.V70* on NM_005426.2) | Frame Shift Del (DEL) | VAF 61/244 reads (25%) | called by mutect2, varscan2
- TP53I11 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- TRBV20OR9-2 | c.305T>C p.I102T | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TRGV4 | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.092); called by muse, varscan2
- TRIM56 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TRIP12 | c.4728T>A p.D1576E | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TTLL6 | c.2515_2517del p.N839del (on ENST00000393382 / NM_001130918.3; = p.N532del on NM_173623.3) | In Frame Del (DEL) | VAF 42/165 reads (25%) | called by mutect2, pindel, varscan2
- TTN | c.40235A>G p.E13412G (on ENST00000591111; = p.E5988G on NM_003319.4) | Missense Mutation (SNP) | VAF 112/367 reads (31%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TYRP1 | c.1154A>T p.N385I | Missense Mutation (SNP) | VAF 66/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UAP1L1 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UGT3A1 | c.941dup p.K315Efs*42 | Frame Shift Ins (INS) | VAF 133/316 reads (42%) | called by mutect2, pindel, varscan2
- UHRF1BP1 | c.1642T>C p.W548R | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ULK2 | c.686del p.N229Tfs*4 | Frame Shift Del (DEL) | VAF 33/82 reads (40%) | called by mutect2, pindel, varscan2
- UPF3A | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UQCRC1 | c.894C>A p.S298R | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- UTP11 | c.279A>T p.Q93H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- VAMP8 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 72/160 reads (45%) | called by muse, mutect2, varscan2
- VEPH1 | c.2425_2427del p.E809del | In Frame Del (DEL) | VAF 74/222 reads (33%) | called by pindel, varscan2
- VGF | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VPS72 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- WAC | c.1877T>C p.I626T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- WDR53 | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 111/222 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR7 | c.3833T>G p.V1278G | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- WNT9B | c.38G>T p.C13F | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- XKR4 | c.1802G>T p.R601M | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- YAP1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 47/125 reads (38%) | called by mutect2, pindel, varscan2
- ZBTB39 | c.1445G>A p.C482Y | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZDHHC11B | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZEB2 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ZFHX2 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZFP36L2 | c.431del p.G144Afs*43 | Frame Shift Del (DEL) | VAF 214/502 reads (43%) | called by mutect2, varscan2
- ZFYVE28 | c.947dup p.E317* | Frame Shift Ins (INS) | VAF 34/114 reads (30%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.2815del p.S939Afs*15 | Frame Shift Del (DEL) | VAF 77/189 reads (41%) | called by mutect2, pindel, varscan2
- ZMYM3 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF142 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF358 | c.394del p.Q132Rfs*35 | Frame Shift Del (DEL) | VAF 42/89 reads (47%) | called by mutect2, pindel, varscan2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 16/153 reads (10%) | called by mutect2, pindel, varscan2
- ZNF462 | c.5452C>T p.P1818S | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF569 | c.1228T>A p.Y410N | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ZNF583 | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF696 | c.14_16del p.G5del | In Frame Del (DEL) | VAF 37/137 reads (27%) | called by pindel, varscan2
- ZNF75D | c.1137T>G p.D379E | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZSCAN25 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZSCAN25 | c.590-6G>A | Splice Region (SNP) | VAF 79/216 reads (37%) | called by muse, mutect2, varscan2
- AATK | c.2799A>G p.R933= (on ENST00000326724 / NM_001080395.3; = p.R830= on NM_004920.2) | Silent (SNP) | VAF 62/140 reads (44%) | called by muse, mutect2, varscan2
- ACBD5 | c.789T>C p.T263= (on ENST00000375888 / NM_001352568.1; = p.T254= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 105/261 reads (40%) | called by muse, mutect2, varscan2
- ACTL6B | c.555G>A p.L185= | Silent (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- ACTN2 | c.987G>A p.K329= | Silent (SNP) | VAF 210/890 reads (24%) | catalogued as rs1185341467; called by muse, mutect2, varscan2
- ACTN3 | c.1260C>T p.H420= | Silent (SNP) | VAF 82/178 reads (46%) | catalogued as rs370647530, COSV72207541; called by muse, mutect2, varscan2
- ACTR5 | c.546T>C p.S182= | Silent (SNP) | VAF 32/213 reads (15%) | called by muse, mutect2, varscan2
- AMH | c.774G>A p.A258= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as rs1384107668; called by muse, mutect2
- ANKRD62 | c.852G>A p.E284= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- ANO5 | c.531G>A p.L177= | Silent (SNP) | VAF 100/277 reads (36%) | called by muse, mutect2, varscan2
- APCDD1 | c.1443A>T p.G481= | Silent (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.1587G>A p.L529= (on ENST00000395184 / NM_001025616.3; = p.L436= on NM_031305.3) | Silent (SNP) | VAF 110/350 reads (31%) | catalogued as rs1306822645; called by muse, mutect2, varscan2
- ARMC9 | c.666T>C p.R222= | Silent (SNP) | VAF 77/145 reads (53%) | called by muse, mutect2, varscan2
- ARV1 | c.723C>T p.G241= | Silent (SNP) | VAF 46/283 reads (16%) | called by muse, mutect2, varscan2
- ATP8A2 | c.3390C>T p.R1130= | Silent (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2, varscan2
- BIRC6 | c.12774C>T p.S4258= | Silent (SNP) | VAF 93/240 reads (39%) | called by muse, mutect2, varscan2
- BRCA1 | c.4131C>T p.S1377= | Silent (SNP) | VAF 155/389 reads (40%) | catalogued as rs80356871, COSV100524139; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRCA2 | c.7893G>T p.L2631= | Silent (SNP) | VAF 47/183 reads (26%) | catalogued as COSV66448660; called by muse, mutect2, varscan2
- BTN1A1 | c.187C>T p.L63= | Silent (SNP) | VAF 90/232 reads (39%) | called by muse, mutect2, varscan2
- BTN2A2 | c.798G>A p.V266= | Silent (SNP) | VAF 69/189 reads (37%) | called by muse, mutect2, varscan2
- C17orf49 | c.6G>T p.T2= | Silent (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- C5orf38 | c.111G>A p.A37= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as rs562112520; called by muse, varscan2
- CACNG7 | c.129G>A p.P43= | Silent (SNP) | VAF 93/199 reads (47%) | catalogued as rs376239971; called by muse, mutect2, varscan2
- CAVIN1 | c.801G>T p.R267= | Silent (SNP) | VAF 174/420 reads (41%) | catalogued as COSV63811808; called by muse, mutect2, varscan2
- CBLC | c.375C>A p.A125= | Silent (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
- CCDC102B | c.405T>C p.S135= | Silent (SNP) | VAF 68/149 reads (46%) | catalogued as rs1431517859; called by muse, mutect2, varscan2
- CCDC181 | c.1251A>G p.L417= (on ENST00000367806 / NM_001300969.1; = p.L416= on NM_021179.2) | Silent (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- CCDC24 | c.540C>A p.I180= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as rs1203961465; called by muse, mutect2, varscan2
- CCL23 | c.376C>T p.L126= | Silent (SNP) | VAF 55/161 reads (34%) | called by muse, mutect2, varscan2
- CDCA7L | c.981T>C p.D327= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs1327409266; called by muse, mutect2, varscan2
- CDH9 | c.2211G>A p.T737= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as rs1256309910, COSV50250898, COSV50492681; called by muse, mutect2, varscan2
- CLSTN1 | c.2598G>A p.V866= (on ENST00000377298 / NM_001009566.3; = p.V856= on NM_014944.4) | Silent (SNP) | VAF 62/145 reads (43%) | called by muse, varscan2
- COIL | c.30G>A p.R10= | Silent (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- COL4A2 | c.153C>T p.C51= | Silent (SNP) | VAF 75/181 reads (41%) | called by muse, mutect2, varscan2
- CTAGE6 | c.1371C>A p.S457= | Silent (SNP) | VAF 81/498 reads (16%) | catalogued as COSV101417901; called by muse, mutect2, varscan2
- CUX2 | c.2781A>G p.S927= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- CX3CL1 | c.420G>A p.P140= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as rs370435863; called by muse, mutect2, varscan2
- DAGLB | c.1974C>T p.C658= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as rs763916685, COSV51703379; called by muse, mutect2, varscan2
- DISP3 | c.1002G>A p.S334= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as COSV53823479; called by muse, mutect2, varscan2
- DNAH3 | c.5430C>T p.D1810= | Silent (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2, varscan2
- DNAH5 | c.6408G>A p.T2136= | Silent (SNP) | VAF 102/218 reads (47%) | catalogued as rs765298305, COSV54230840; called by muse, mutect2, varscan2
- DNM2 | c.2163C>T p.D721= (on ENST00000355667 / NM_001005360.3; = p.D717= on NM_004945.3) | Silent (SNP) | VAF 151/362 reads (42%) | catalogued as rs770491381; called by muse, mutect2, varscan2
- DPYSL4 | c.177C>T p.D59= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs142922640; called by muse, mutect2, varscan2
- ELFN2 | c.1866G>A p.A622= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs1238188762, COSV68745340, COSV68746598; called by muse, mutect2, varscan2
- ESRRA | c.942G>A p.R314= | Silent (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- EXO1 | c.819C>T p.N273= | Silent (SNP) | VAF 111/509 reads (22%) | catalogued as rs1002966274, COSV100799650; called by muse, mutect2, varscan2
- EXO1 | c.1014C>T p.I338= | Silent (SNP) | VAF 69/347 reads (20%) | catalogued as rs372371375; called by muse, mutect2, varscan2
- EXOSC9 | c.462C>T p.I154= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs748947224, COSV99697160; called by muse, mutect2, varscan2
- FAM110C | c.444C>T p.N148= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs769473639; called by mutect2, varscan2
- FARP1 | c.1527C>A p.A509= | Silent (SNP) | VAF 51/132 reads (39%) | called by muse, mutect2, varscan2
- FCGBP | c.10437C>A p.P3479= | Silent (SNP) | VAF 50/544 reads (9%) | called by muse, mutect2
- FER1L6 | c.1782G>A p.L594= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as rs1242032306; called by muse, mutect2, varscan2
- FHAD1 | c.537C>T p.D179= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs768911697; called by muse, mutect2
- FRMD8 | c.228G>A p.A76= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as rs371990682; called by muse, mutect2, varscan2
- FUBP1 | c.183G>C p.G61= | Silent (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- GCM2 | c.391C>A p.R131= | Silent (SNP) | VAF 114/338 reads (34%) | catalogued as COSV65275658; called by muse, mutect2, varscan2
- GJC2 | c.906C>T p.R302= | Silent (SNP) | VAF 77/298 reads (26%) | catalogued as rs749522785; called by muse, mutect2, varscan2
- GLB1 | c.1647G>A p.P549= | Silent (SNP) | VAF 102/263 reads (39%) | catalogued as rs772573490; called by muse, mutect2, varscan2
- GLI1 | c.2079T>C p.T693= | Silent (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- GLRA2 | c.927A>G p.P309= | Silent (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- GPA33 | c.675G>A p.T225= | Silent (SNP) | VAF 57/245 reads (23%) | catalogued as rs374776660, COSV63302573; called by muse, mutect2, varscan2
- GPR68 | c.684G>A p.R228= | Silent (SNP) | VAF 53/145 reads (37%) | catalogued as rs759612571; called by muse, mutect2, varscan2
- HELZ2 | c.1618C>T p.L540= | Silent (SNP) | VAF 116/301 reads (39%) | called by muse, mutect2, varscan2
- HERC1 | c.5421T>A p.L1807= | Silent (SNP) | VAF 127/270 reads (47%) | called by muse, mutect2, varscan2
- HOXA11 | c.240C>A p.A80= | Silent (SNP) | VAF 74/183 reads (40%) | called by muse, mutect2, varscan2
- HOXD4 | c.315G>A p.A105= | Silent (SNP) | VAF 158/393 reads (40%) | catalogued as COSV60459863; called by muse, mutect2, varscan2
- HRNR | c.1164C>T p.G388= | Silent (SNP) | VAF 73/332 reads (22%) | catalogued as COSV64263303; called by muse, mutect2, varscan2
- IFITM5 | c.285G>A p.V95= | Silent (SNP) | VAF 137/332 reads (41%) | called by muse, mutect2, varscan2
- IL20RA | c.1464G>A p.R488= | Silent (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- IMPA1 | c.324A>T p.S108= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- INTS6 | c.531C>T p.G177= | Silent (SNP) | VAF 63/161 reads (39%) | called by muse, mutect2, varscan2
- KIAA2013 | c.1492C>T p.L498= | Silent (SNP) | VAF 53/127 reads (42%) | called by muse, mutect2, varscan2
- LAMA5 | c.9798C>T p.F3266= | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as rs770986344, COSV53356522; called by muse, mutect2, varscan2
- LENG9 | c.504C>T p.H168= | Silent (SNP) | VAF 57/137 reads (42%) | called by muse, mutect2, varscan2
- LHX2 | c.1050C>A p.A350= | Silent (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- LIFR | c.945T>G p.V315= | Silent (SNP) | VAF 108/227 reads (48%) | called by muse, mutect2, varscan2
- LORICRIN | c.318C>T p.S106= | Silent (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- LRWD1 | c.693C>A p.A231= | Silent (SNP) | VAF 63/124 reads (51%) | called by muse, mutect2, varscan2
- LYPD3 | c.756C>A p.T252= | Silent (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- MAGI1 | c.3621A>T p.S1207= (on ENST00000402939 / NM_001033057.2; = p.S1236= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 93/225 reads (41%) | called by muse, mutect2, varscan2
- MAGI2 | c.2670C>T p.Y890= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs542077951, COSV100836713, COSV62661837; called by muse, mutect2, varscan2
- MALRD1 | c.2952T>C p.I984= | Silent (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- MED13 | c.2835T>A p.V945= | Silent (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- MYH13 | c.1755C>T p.A585= | Silent (SNP) | VAF 67/148 reads (45%) | catalogued as rs1040817237; called by muse, mutect2, varscan2
- NT5DC2 | c.888C>T p.V296= | Silent (SNP) | VAF 67/166 reads (40%) | called by muse, mutect2, varscan2
- OGFR | c.513C>T p.Y171= | Silent (SNP) | VAF 100/255 reads (39%) | catalogued as rs1017118352; called by muse, mutect2, varscan2
- PAXIP1 | c.1380G>A p.P460= | Silent (SNP) | VAF 70/194 reads (36%) | catalogued as rs371796152; called by muse, varscan2
- PCDH12 | c.2427C>T p.D809= | Silent (SNP) | VAF 93/233 reads (40%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1671C>T p.D557= | Silent (SNP) | VAF 214/526 reads (41%) | catalogued as rs1278883144, COSV65376573; called by muse, mutect2, varscan2
- PDLIM5 | c.1756C>T p.L586= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as rs905198639; called by muse, mutect2, varscan2
- PHF14 | c.2031T>C p.S677= | Silent (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- PIGR | c.639C>T p.S213= | Silent (SNP) | VAF 107/459 reads (23%) | catalogued as rs761979881, COSV62903817; called by muse, mutect2, varscan2
- PLCG2 | c.1440G>A p.E480= | Silent (SNP) | VAF 75/171 reads (44%) | called by muse, mutect2, varscan2
- PLPP3 | c.804C>T p.C268= | Silent (SNP) | VAF 44/166 reads (27%) | called by muse, mutect2, varscan2
- PLXNB3 | c.2323C>T p.L775= | Silent (SNP) | VAF 70/217 reads (32%) | called by muse, mutect2, varscan2
- PML | c.2323C>T p.L775= | Silent (SNP) | VAF 89/229 reads (39%) | called by muse, mutect2, varscan2
- POU3F4 | c.675C>T p.N225= | Silent (SNP) | VAF 127/295 reads (43%) | catalogued as COSV64538658; called by muse, mutect2, varscan2
- PPP2CA | c.513G>A p.S171= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as rs778165477, COSV51538643; called by muse, mutect2, varscan2
- PRDM4 | c.723C>T p.S241= | Silent (SNP) | VAF 137/283 reads (48%) | called by muse, mutect2, varscan2
- PRKAG2 | c.573C>A p.I191= | Silent (SNP) | VAF 156/416 reads (38%) | catalogued as COSV55222523; called by muse, mutect2, varscan2
- PRTG | c.2502C>T p.D834= | Silent (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- PTGDR2 | c.501C>T p.F167= | Silent (SNP) | VAF 23/214 reads (11%) | catalogued as rs777347417, COSV99920200; called by muse, mutect2, varscan2
- RALGDS | c.1440G>A p.S480= | Silent (SNP) | VAF 88/255 reads (35%) | catalogued as rs139209966; called by muse, mutect2, varscan2
- RANBP2 | c.7617A>T p.S2539= | Silent (SNP) | VAF 174/622 reads (28%) | catalogued as rs143675099; ClinVar: likely benign; called by mutect2, varscan2
- RBL2 | c.2511G>A p.S837= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as rs772626314, COSV50883062; called by muse, mutect2, varscan2
- RBP3 | c.663C>T p.Y221= | Silent (SNP) | VAF 191/460 reads (42%) | catalogued as rs782674053; called by muse, mutect2, varscan2
- REXO1 | c.435C>T p.F145= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as rs772137414; called by muse, mutect2, varscan2
- RIMS2 | c.1566G>A p.T522= (on ENST00000666250 / NM_001348490.2; = p.T330= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 64/134 reads (48%) | catalogued as rs1157732703, COSV51721068, COSV99192726; called by muse, mutect2, varscan2
- RLN2 | c.528T>C p.C176= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV57731071; called by muse, varscan2
- RNF128 | c.12G>A p.P4= | Silent (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.870G>A p.Q290= | Silent (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- RUSC2 | c.4401C>T p.S1467= | Silent (SNP) | VAF 33/160 reads (21%) | called by muse, mutect2, varscan2
- SCAF1 | c.1638G>A p.P546= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs1266889554; called by muse, mutect2, varscan2
- SERPINB3 | c.555G>A p.Q185= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- SIX2 | c.315C>A p.A105= | Silent (SNP) | VAF 124/251 reads (49%) | catalogued as COSV100284181; called by muse, mutect2, varscan2
- SLC4A4 | c.1458T>C p.T486= (on ENST00000264485 / NM_001098484.3; = p.T442= on NM_003759.4) | Silent (SNP) | VAF 24/258 reads (9%) | called by muse, mutect2
- SLC5A2 | c.1209G>A p.T403= | Silent (SNP) | VAF 109/265 reads (41%) | catalogued as rs768873458, COSV57892468; called by muse, mutect2, varscan2
- SMARCC2 | c.3462A>T p.P1154= | Silent (SNP) | VAF 115/289 reads (40%) | called by muse, mutect2, varscan2
- SNW1 | c.789A>G p.P263= | Silent (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- SOBP | c.1371G>A p.S457= | Silent (SNP) | VAF 72/222 reads (32%) | catalogued as rs1481359566, COSV58000737; called by muse, mutect2, varscan2
- SOX10 | c.519C>T p.Y173= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as CM101962; called by muse, mutect2, varscan2
- SOX18 | c.534G>A p.A178= | Silent (SNP) | VAF 166/353 reads (47%) | called by muse, mutect2, varscan2
- SP4 | c.1113A>G p.E371= | Silent (SNP) | VAF 114/259 reads (44%) | called by muse, mutect2, varscan2
- SRCAP | c.6942C>A p.R2314= | Silent (SNP) | VAF 40/176 reads (23%) | catalogued as COSV52680989; called by muse, mutect2, varscan2
- STK11 | c.696C>T p.S232= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs566823619; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- SUPT3H | c.867C>T p.S289= (on ENST00000371460 / NM_181356.3; = p.S278= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as rs758205609; called by muse, mutect2, varscan2
- TAF1L | c.2520G>A p.R840= | Silent (SNP) | VAF 160/425 reads (38%) | catalogued as COSV54262279; called by muse, mutect2, varscan2
- TBCCD1 | c.1011C>T p.C337= | Silent (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- TBL2 | c.45G>A p.L15= | Silent (SNP) | VAF 104/274 reads (38%) | catalogued as COSV59788485; called by muse, mutect2, varscan2
- TJP2 | c.1941T>C p.A647= | Silent (SNP) | VAF 61/162 reads (38%) | called by muse, mutect2, varscan2
- TMCC2 | c.363T>C p.D121= | Silent (SNP) | VAF 128/576 reads (22%) | called by muse, mutect2, varscan2
- TMEM131 | c.3318C>A p.T1106= | Silent (SNP) | VAF 40/112 reads (36%) | called by muse, mutect2, varscan2
- TNPO3 | c.2649A>T p.T883= | Silent (SNP) | VAF 53/150 reads (35%) | called by muse, mutect2, varscan2
- TOR4A | c.699G>A p.A233= | Silent (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- TTC6 | c.636C>T p.D212= | Silent (SNP) | VAF 80/191 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.85923G>A p.T28641= (on ENST00000591111; = p.T21217= on NM_003319.4) | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs753475617, COSV100625272; called by muse, mutect2, varscan2
- TTN | c.9402C>T p.N3134= (on ENST00000591111; = p.N3088= on NM_003319.4) | Silent (SNP) | VAF 41/258 reads (16%) | catalogued as rs587780987, COSV60001297, COSV60104666; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- VILL | c.39C>T p.G13= | Silent (SNP) | VAF 72/151 reads (48%) | catalogued as COSV52185713; called by muse, mutect2, varscan2
- WDR24 | c.1599G>A p.E533= (on ENST00000248142; = p.E403= on NM_032259.4) | Silent (SNP) | VAF 98/251 reads (39%) | called by muse, mutect2, varscan2
- WDR72 | c.1701G>A p.P567= | Silent (SNP) | VAF 97/235 reads (41%) | catalogued as rs776018576, COSV100855347; called by muse, mutect2, varscan2
- WDR97 | c.1455G>A p.P485= | Silent (SNP) | VAF 59/131 reads (45%) | called by muse, mutect2, varscan2
- WFDC2 | c.111C>G p.P37= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as rs772425031; called by muse, mutect2, varscan2
- ZNF146 | c.438T>C p.H146= | Silent (SNP) | VAF 60/177 reads (34%) | catalogued as rs982235410, COSV61931478; called by muse, mutect2, varscan2
- ZNF335 | c.1776T>C p.C592= | Silent (SNP) | VAF 55/121 reads (45%) | called by muse, mutect2, varscan2
- ZNF460 | c.918A>G p.K306= | Silent (SNP) | VAF 49/97 reads (51%) | catalogued as COSV64416573; called by muse, mutect2, varscan2
- ZNF479 | c.1224C>G p.P408= | Silent (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- ZNF527 | c.1572A>G p.K524= | Silent (SNP) | VAF 64/175 reads (37%) | called by muse, mutect2, varscan2
- ABCB10 | c.1951-11del | Intron (DEL) | VAF 18/113 reads (16%) | catalogued as rs753546411; called by mutect2, varscan2
- ABCG1 | c.42+651_42+652del | Intron (DEL) | VAF 67/203 reads (33%) | catalogued as rs748929146; called by mutect2, pindel, varscan2
- AC073621.1 | n.695C>T | RNA (SNP) | VAF 54/152 reads (36%) | catalogued as rs773199890; called by muse, mutect2, varscan2
122 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 122 other) are not listed here.
